Somatic mutation profile of tumor specimen C3N-03074-02 (aliquot CPT0209170006) from CPTAC case C3N-03074, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 53.4 years (19,500 days).
Specimen C3N-03074-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78bb6eac-0e07-48c7-bb83-44d3b779ed93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03074-32 (Blood Derived Normal), aliquot CPT0209220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d08824e-8036-4359-9f41-c34b2ccde39d

The open-access MAF lists 102 somatic variants for this specimen: 62 protein-altering or splice-affecting, 28 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 28, Intron 8, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 3, 5'Flank 1, 3'Flank 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 320/749 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- NEB | c.1569+1G>A p.X523_splice | Splice Site (SNP) | VAF 21/142 reads (15%) | catalogued as rs1553605553, CS1413956, COSV51447294, COSV99423800; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 131/344 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTRT1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.422); catalogued as rs200995211, COSV64419336, COSV64420085; called by muse, mutect2, varscan2
- ARHGEF26 | c.763C>G p.L255V | Missense Mutation (SNP) | VAF 46/296 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV62852573; called by muse, mutect2, varscan2
- CAMSAP3 | c.3049C>T p.R1017W | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs1206197408; called by muse, mutect2, varscan2
- CD163L1 | c.2686+1G>A p.X896_splice | Splice Site (SNP) | VAF 39/204 reads (19%) | catalogued as rs193151180, CS153145; called by muse, mutect2, varscan2
- CSMD1 | c.5207G>A p.R1736H (on ENST00000520002; = p.R1735H on NM_033225.6) | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs992855692, COSV59304995; called by muse, mutect2, varscan2
- DZIP3 | c.793A>G p.I265V | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs1179282160, COSV100847843; called by muse, mutect2, varscan2
- EIF2B5 | c.845G>A p.R282Q (on ENST00000647909; = p.R274Q on NM_003907.3) | Missense Mutation (SNP) | VAF 22/501 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs1460067929, COSV56606484; called by muse, mutect2
- EPX | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 130/596 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768211646, COSV56596892; called by muse, mutect2, varscan2
- FAT3 | c.12352G>A p.G4118S | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369315276; called by muse, mutect2, varscan2
- MIER3 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 40/252 reads (16%) | catalogued as rs1327305626; called by muse, mutect2, varscan2
- MUC5AC | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 101/294 reads (34%) | SIFT deleterious (0); catalogued as rs1406168432; called by muse, mutect2, varscan2
- OR2T6 | c.180C>G p.Y60* | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | catalogued as COSV63216949; called by muse, mutect2, varscan2
- OR8B8 | c.588G>C p.E196D | Missense Mutation (SNP) | VAF 92/462 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.297); catalogued as COSV60144336; called by muse, mutect2, varscan2
- OTUD7A | c.2515G>A p.G839R (on ENST00000307050 / NM_001382637.1; = p.G832R on NM_130901.3) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs1219640234; called by muse, mutect2, varscan2
- PCDHGA1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 79/159 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs140226913, COSV65296451; called by muse, mutect2, varscan2
- PTCHD4 | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as rs778360888; called by muse, mutect2, varscan2
- THSD7B | c.2401A>G p.K801E | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as rs766594988; called by muse, mutect2, varscan2
- VWF | c.4025G>A p.R1342H | Missense Mutation (SNP) | VAF 60/467 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs527483960, COSV54625471; called by muse, mutect2, varscan2
- ZNF737 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 106/537 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV71199796; called by muse, mutect2, varscan2
- ACKR3 | c.638A>C p.E213A | Missense Mutation (SNP) | VAF 69/353 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- BRCA2 | c.5401C>G p.P1801A | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- CALCR | c.742T>G p.C248G (on ENST00000649521 / NM_001164737.2; = p.C232G on NM_001742.4) | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- COL9A2 | c.1676G>T p.G559V | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CUX1 | c.1265G>T p.R422L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- DNAL4 | c.252G>T p.E84D | Missense Mutation (SNP) | VAF 22/241 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.261); called by muse, mutect2
- DUOX2 | c.1575-1G>T p.X525_splice | Splice Site (SNP) | VAF 20/504 reads (4%) | called by muse, mutect2
- FAM124A | c.443A>T p.Q148L (on ENST00000322475 / NM_001242312.2; = p.Q184L on NM_145019.4) | Missense Mutation (SNP) | VAF 85/233 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM166C | c.378A>T p.Q126H | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.28); called by muse, mutect2
- FAT4 | c.14648A>G p.E4883G | Missense Mutation (SNP) | VAF 123/371 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- GPBP1L1 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 33/372 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.356); called by muse, mutect2
- GPRC5A | c.413C>G p.A138G | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- INTS11 | c.559T>G p.L187V | Missense Mutation (SNP) | VAF 40/460 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- KIR3DL3 | c.1038G>T p.W346C | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.11); called by muse, mutect2
- KNL1 | c.3076C>G p.P1026A (on ENST00000346991 / NM_170589.5; = p.P1000A on NM_144508.5) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.124); called by muse, mutect2
- KPTN | c.892C>A p.Q298K | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- LAMC1 | c.4351_4353delinsA p.F1451Sfs*8 | Frame Shift Del (DEL) | VAF 34/134 reads (25%) | called by pindel, varscan2*
- LRRN3 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- MEIOC | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MMP9 | c.991A>G p.T331A | Missense Mutation (SNP) | VAF 97/431 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- NKD2 | c.154G>T p.G52W | Missense Mutation (SNP) | VAF 40/358 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR10S1 | c.116T>A p.L39H | Missense Mutation (SNP) | VAF 54/345 reads (16%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- OR2M4 | c.61A>T p.S21C | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- OR9K2 | c.734A>G p.Y245C (on ENST00000305377; = p.Y223C on NM_001005243.1) | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.25); called by muse, mutect2
- PHF21B | c.1101C>A p.C367* | Nonsense Mutation (SNP) | VAF 27/167 reads (16%) | called by muse, mutect2, varscan2
- PLAT | c.121del p.C41Afs*8 | Frame Shift Del (DEL) | VAF 27/90 reads (30%) | called by mutect2, pindel, varscan2
- PRMT6 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 62/239 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRSS56 | c.811T>C p.C271R | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- RLF | c.2432T>A p.F811Y | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 103/622 reads (17%) | called by muse, mutect2, varscan2
- SFPQ | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC8B1 | c.599G>A p.R200K | Missense Mutation (SNP) | VAF 47/254 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- TTC6 | c.1439A>G p.E480G | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.099); called by muse, varscan2
- TTN | c.90949C>T p.R30317* (on ENST00000591111; = p.R22893* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 28/302 reads (9%) | called by muse, mutect2
- TUSC1 | c.436G>T p.G146C | Missense Mutation (SNP) | VAF 162/523 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- WDR86 | c.547G>C p.G183R | Missense Mutation (SNP) | VAF 75/402 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- YIPF5 | c.642del p.I215Lfs*17 | Frame Shift Del (DEL) | VAF 28/114 reads (25%) | called by mutect2, pindel, varscan2
- ZNF160 | c.773A>T p.K258I | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF536 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZSCAN26 | c.841G>T p.G281C (on ENST00000623276 / NM_001111039.2; = p.G147C on NM_152736.5) | Missense Mutation (SNP) | VAF 39/299 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- A2M | c.1641T>A p.P547= | Silent (SNP) | VAF 42/231 reads (18%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.2541G>A p.R847= | Silent (SNP) | VAF 55/414 reads (13%) | catalogued as COSV57010673; called by muse, mutect2, varscan2
- ADAMTS6 | c.519C>G p.T173= | Silent (SNP) | VAF 19/187 reads (10%) | called by muse, mutect2, varscan2
- APBB1IP | c.1734G>A p.P578= | Silent (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- BRINP3 | c.1335C>T p.D445= | Silent (SNP) | VAF 24/291 reads (8%) | catalogued as rs746938927, COSV66514992; called by muse, mutect2
- CLINT1 | c.1374A>G p.R458= | Silent (SNP) | VAF 74/126 reads (59%) | catalogued as COSV99753806; called by muse, mutect2
- DCDC1 | c.2628C>G p.G876= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100337956; called by muse, mutect2, varscan2
- DHX33 | c.1974C>T p.L658= | Silent (SNP) | VAF 22/423 reads (5%) | called by muse, mutect2
- IGKV2D-30 | c.279C>T p.G93= | Silent (SNP) | VAF 92/764 reads (12%) | called by muse, mutect2, varscan2
- KRTAP10-11 | c.819C>T p.C273= | Silent (SNP) | VAF 93/299 reads (31%) | catalogued as rs781918376, COSV58177562; called by muse, mutect2, varscan2
- MATK | c.1320G>T p.G440= (on ENST00000310132 / NM_139355.3; = p.G441= on NM_002378.4) | Silent (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2, varscan2
- MUC16 | c.37995C>A p.I12665= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV101201313; called by muse, mutect2, varscan2
- NEURL1B | c.582C>T p.S194= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs542963788; called by mutect2, varscan2
- NSMCE3 | c.267G>A p.V89= | Silent (SNP) | VAF 35/148 reads (24%) | called by muse, mutect2, varscan2
- OR10S1 | c.117C>T p.L39= | Silent (SNP) | VAF 55/349 reads (16%) | catalogued as rs138137631, COSV101602496, COSV73343086; called by muse, mutect2, varscan2
- OR51G1 | c.498G>A p.K166= | Silent (SNP) | VAF 48/230 reads (21%) | catalogued as rs1468903205; called by muse, mutect2, varscan2
- OTUD6A | c.843G>T p.G281= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- PACS2 | c.774G>A p.L258= | Silent (SNP) | VAF 44/211 reads (21%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.1428A>G p.A476= | Silent (SNP) | VAF 107/431 reads (25%) | called by muse, mutect2, varscan2
- PLA2G4F | c.1014C>G p.A338= | Silent (SNP) | VAF 22/250 reads (9%) | called by muse, mutect2
- PPP1R16B | c.630G>A p.A210= | Silent (SNP) | VAF 53/273 reads (19%) | catalogued as rs780078853, COSV55375392; called by muse, mutect2, varscan2
- RUSF1 | c.1248C>T p.S416= | Silent (SNP) | VAF 18/230 reads (8%) | catalogued as rs1340750835, COSV100393051; called by muse, mutect2
- TAF2 | c.2220C>T p.N740= | Silent (SNP) | VAF 18/425 reads (4%) | called by muse, mutect2
- TEX11 | c.1962G>A p.V654= (on ENST00000344304; = p.V639= on NM_031276.3) | Silent (SNP) | VAF 13/130 reads (10%) | catalogued as COSV60229306; called by muse, mutect2, varscan2
- TTC24 | c.243C>T p.C81= | Silent (SNP) | VAF 22/381 reads (6%) | catalogued as rs751453760, COSV63998662; called by muse, mutect2
- URGCP | c.648G>C p.V216= (on ENST00000453200 / NM_001077663.3; = p.V207= on NM_017920.4) | Silent (SNP) | VAF 50/742 reads (7%) | called by muse, mutect2
- ZFHX4 | c.5733G>A p.A1911= | Silent (SNP) | VAF 114/213 reads (54%) | catalogued as rs377346853; called by muse, mutect2, varscan2
- ZFP82 | c.675C>G p.L225= | Silent (SNP) | VAF 39/378 reads (10%) | catalogued as COSV67564856; called by muse, mutect2, varscan2
- ANKRD11 | c.-429G>A | 5'UTR (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- FTCD | c.907-38C>T | Intron (SNP) | VAF 37/136 reads (27%) | catalogued as rs192911499; called by muse, mutect2, varscan2
- GNB1L | c.*49G>T | 3'UTR (SNP) | VAF 24/200 reads (12%) | called by muse, mutect2, varscan2
- GPR161 | c.-139+778C>A | Intron (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- NSG2 | c.213+1932C>A | Intron (SNP) | VAF 118/255 reads (46%) | catalogued as rs1189498321; called by muse, mutect2, varscan2
- RNF10 | c.157+4428G>T | Intron (SNP) | VAF 39/187 reads (21%) | catalogued as rs972319106; called by muse, mutect2, varscan2
- SNX32 | c.253-50G>A | Intron (SNP) | VAF 40/310 reads (13%) | called by muse, mutect2, varscan2
- SPG7 | c.183+305A>G | Intron (SNP) | VAF 69/313 reads (22%) | catalogued as rs781760939; called by muse, mutect2, varscan2
- TPM3 | chr1:154159009 G>C | 3'Flank (SNP) | VAF 66/645 reads (10%) | called by muse, mutect2, varscan2
- XKR4 | c.806+36832A>T | Intron (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
- ZIC4 | c.688+1921del | Intron (DEL) | VAF 24/273 reads (9%) | called by pindel, varscan2*
- ZNF436 | chr1:23371491 T>C | 5'Flank (SNP) | VAF 49/229 reads (21%) | called by muse, mutect2, varscan2
